Somatic mutation profile of tumor specimen TCGA-AK-3455-01A (aliquot TCGA-AK-3455-01A-01D-0966-08) from TCGA case TCGA-AK-3455, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 71.8 years (26,221 days).
Specimen TCGA-AK-3455-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6dfcdb9-2b77-41f1-85df-765a84634bfd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AK-3455-10A (Blood Derived Normal), aliquot TCGA-AK-3455-10A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d01e4851-501b-4151-9d5a-ed083ae2f100

The open-access MAF lists 62 somatic variants for this specimen: 50 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 10, Frame Shift Del 4, Frame Shift Ins 2, Nonsense Mutation 2, RNA 1, Splice Site 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOXE3 | c.60C>A p.D20E | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58554727; called by muse, mutect2, varscan2
- ARHGAP26 | c.1861A>T p.N621Y | Missense Mutation (SNP) | VAF 67/276 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as COSV50828614; called by muse, mutect2, varscan2
- ARID1B | c.6308T>G p.V2103G | Missense Mutation (SNP) | VAF 20/570 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51659995; called by muse, mutect2
- CAMK2G | c.251G>C p.G84A | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.03); catalogued as COSV59481597; called by muse, mutect2, varscan2
- CCDC146 | c.1124G>T p.W375L | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV53547529; called by muse, mutect2, varscan2
- CPED1 | c.1062-1G>T p.X354_splice | Splice Site (SNP) | VAF 27/119 reads (23%) | catalogued as COSV60001342, COSV60006535; called by muse, mutect2, varscan2
- CUX1 | c.3934A>G p.S1312G | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV52897972; called by muse, mutect2, varscan2
- DCDC1 | c.499C>A p.H167N | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as COSV60841251; called by muse, mutect2, varscan2
- DMGDH | c.379G>C p.V127L | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as COSV54862980; called by muse, mutect2, varscan2
- DOCK4 | c.2080C>T p.R694W | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs773221466, COSV70234797, COSV70241471; called by muse, mutect2, varscan2
- FCN1 | c.332G>C p.C111S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV65662254; called by muse, mutect2, varscan2
- FPGT | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 72/256 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63835221; called by muse, mutect2, varscan2
- IP6K3 | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53389710, COSV53390070; called by muse, mutect2, varscan2
- JADE1 | c.1046T>G p.M349R | Missense Mutation (SNP) | VAF 21/297 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56905714; called by muse, mutect2
- KCNJ2 | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 80/270 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as rs140147979; called by muse, mutect2, varscan2
- KIDINS220 | c.4915A>G p.I1639V | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs376497503; called by muse, mutect2, varscan2
- LRP4 | c.1279C>T p.R427W | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs770749728, COSV66135542; called by muse, mutect2, varscan2
- MAGEB16 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.098); catalogued as COSV67873877, COSV67874425; called by muse, mutect2, varscan2
- MAN2C1 | c.793T>C p.W265R | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51228355; called by muse, mutect2, varscan2
- MFSD6L | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 62/242 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs377452108; called by muse, mutect2, varscan2
- MYH15 | c.5008G>C p.D1670H | Missense Mutation (SNP) | VAF 117/385 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56309053, COSV56316166; called by muse, mutect2, varscan2
- NFKBIZ | c.321G>C p.Q107H | Missense Mutation (SNP) | VAF 67/307 reads (22%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.007); catalogued as COSV58200180; called by muse, mutect2, varscan2
- PARP14 | c.5389A>C p.I1797L | Missense Mutation (SNP) | VAF 114/371 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71734606; called by muse, mutect2, varscan2
- PDK1 | c.901A>G p.I301V | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.037); catalogued as COSV56375248; called by muse, mutect2, varscan2
- PLD5 | c.499C>A p.Q167K (on ENST00000442594; = p.Q105K on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs752229269, COSV59143660; called by muse, mutect2, varscan2
- RAD51AP2 | c.1355T>C p.I452T | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV67587919; called by muse, mutect2, varscan2
- RPS6KC1 | c.515T>C p.V172A | Missense Mutation (SNP) | VAF 75/347 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV65298913; called by muse, mutect2, varscan2
- RTN3 | c.1864G>A p.E622K (on ENST00000377819 / NM_001265589.2; = p.E603K on NM_201428.3) | Missense Mutation (SNP) | VAF 63/239 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.162); catalogued as rs1159840049, COSV58026918, COSV58028391; called by muse, mutect2, varscan2
- SETD2 | c.4949T>C p.F1650S | Missense Mutation (SNP) | VAF 82/202 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57436736; called by muse, mutect2, varscan2
- SI | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746292703, COSV52276512; called by muse, mutect2, varscan2
- SLITRK6 | c.2132G>A p.G711E | Missense Mutation (SNP) | VAF 198/756 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV68389344; called by muse, mutect2, varscan2
- SMARCB1 | c.964C>T p.Q322* (on ENST00000263121; = p.Q368* on NM_003073.5) | Nonsense Mutation (SNP) | VAF 38/148 reads (26%) | catalogued as COSV51954323; called by muse, mutect2, varscan2
- SNED1 | c.1655A>G p.N552S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780070010, COSV60023442; called by muse, mutect2, varscan2
- SPATS2L | c.632A>G p.D211G | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as COSV62347795; called by muse, mutect2, varscan2
- TBL1XR1 | c.680A>G p.D227G | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61790374; called by muse, mutect2, varscan2
- TEX14 | c.4221T>G p.D1407E (on ENST00000240361 / NM_001201457.2; = p.D1361E on NM_031272.5) | Missense Mutation (SNP) | VAF 74/295 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53616029; called by muse, mutect2, varscan2
- TGM7 | c.1694T>G p.L565R | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV71772763; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2281C>T p.Q761* | Nonsense Mutation (SNP) | VAF 16/178 reads (9%) | catalogued as COSV51955045; called by muse, mutect2
- VPS39 | c.512C>T p.A171V (on ENST00000348544 / NM_001301138.2; = p.A160V on NM_015289.5) | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.26); catalogued as rs760177028, COSV58789395; called by muse, mutect2, varscan2
- ZFHX4 | c.191T>G p.F64C | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.655); catalogued as COSV50731907; called by muse, varscan2
- ZFP37 | c.664G>C p.G222R | Missense Mutation (SNP) | VAF 86/387 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.025); catalogued as COSV65286760; called by muse, varscan2
- ZFPM2 | c.655T>G p.Y219D | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101023483, COSV65873389; called by muse, mutect2, varscan2
- ZNF804B | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV60825791; called by muse, mutect2, varscan2
- CASQ2 | c.1071_1072insTG p.L358Cfs*14 | Frame Shift Ins (INS) | VAF 41/162 reads (25%) | called by mutect2, pindel, varscan2
- CUX1 | c.2229dup p.K744Qfs*29 | Frame Shift Ins (INS) | VAF 96/384 reads (25%) | called by mutect2, pindel, varscan2
- MED13 | c.5132_5137del p.L1711_K1712del | In Frame Del (DEL) | VAF 83/312 reads (27%) | called by mutect2, pindel, varscan2
- PIP5K1A | c.975_976del p.L326Dfs*5 (on ENST00000368888 / NM_001135638.2; = p.L313Dfs*5 on NM_003557.3) | Frame Shift Del (DEL) | VAF 26/132 reads (20%) | called by pindel, varscan2
- SAMHD1 | c.463del p.Y155Mfs*15 | Frame Shift Del (DEL) | VAF 34/167 reads (20%) | called by mutect2, pindel, varscan2
- VHL | c.349del p.W117Gfs*42 | Frame Shift Del (DEL) | VAF 88/279 reads (32%) | called by mutect2, pindel, varscan2
- ZNF408 | c.1664del p.V555Gfs*146 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | called by mutect2, pindel, varscan2
- AQP4 | c.762A>T p.P254= | Silent (SNP) | VAF 100/410 reads (24%) | catalogued as COSV67218577; called by muse, mutect2, varscan2
- CDH18 | c.384T>G p.A128= | Silent (SNP) | VAF 71/278 reads (26%) | catalogued as COSV56918947; called by muse, mutect2, varscan2
- DOCK10 | c.6156G>A p.V2052= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV51386681, COSV51425575; called by muse, mutect2, varscan2
- GABRA5 | c.1293C>A p.I431= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs776674172, COSV59479043, COSV59479784; called by muse, mutect2, varscan2
- KCNQ1 | c.1057C>T p.L353= | Silent (SNP) | VAF 40/208 reads (19%) | catalogued as COSV50107076; called by muse, mutect2, varscan2
- MTRF1L | c.97C>T p.L33= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV65869694; called by muse, mutect2, varscan2
- MUC16 | c.22815C>T p.P7605= | Silent (SNP) | VAF 37/124 reads (30%) | catalogued as COSV67462644; called by muse, mutect2, varscan2
- NLRP8 | c.2205A>G p.Q735= | Silent (SNP) | VAF 36/135 reads (27%) | catalogued as rs1337200635, COSV52586626; called by muse, mutect2, varscan2
- TAAR5 | c.816G>A p.T272= | Silent (SNP) | VAF 44/157 reads (28%) | catalogued as rs1386458034, COSV57798941; called by muse, mutect2, varscan2
- TSLP | c.99C>T p.N33= | Silent (SNP) | VAF 70/226 reads (31%) | catalogued as COSV61291577; called by muse, mutect2, varscan2
- CCNQP1 | n.392C>G | RNA (SNP) | VAF 22/128 reads (17%) | called by muse, mutect2, varscan2
- ZNF646 | c.*1204C>G | 3'UTR (SNP) | VAF 8/35 reads (23%) | catalogued as COSV54924013, COSV99762596; called by muse, mutect2, varscan2
